FM case AD15595 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/88212cad-0353-422b-89f3-6ccd8363db5d

Female, 67.2 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the fallopian tube; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
